Somatic mutation profile of tumor specimen 0DLBMS from CCDI case PBBZFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Liver; Age at diagnosis: 12.2 years (4,474 days).
Specimen 0DLBMS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85464059-41c0-4a29-aabe-974e17a78150.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBM0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc8d5c80-39fa-43de-a6d9-90aed2dc8ad5

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Silent 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 127/903 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1266844562; called by muse, mutect2, varscan2
- SGK2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 169/419 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs759387934; called by muse, mutect2, varscan2
- ATP13A4 | c.2316+1G>A p.X772_splice | Splice Site (SNP) | VAF 165/339 reads (49%) | called by muse, mutect2, varscan2
- CNGB3 | c.1762T>C p.S588P | Missense Mutation (SNP) | VAF 128/416 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, varscan2
- PPP4R3A | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIA1 | c.826G>A p.G276S (on ENST00000433529 / NM_001351511.1; = p.G265S on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- XRN1 | c.3764A>C p.E1255A | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZBTB40 | c.2298G>T p.V766= | Silent (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
- COMP | c.1136-47C>T | Intron (SNP) | VAF 101/315 reads (32%) | called by muse, mutect2, varscan2
- CYB5R3 | c.154-23A>G | Intron (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- PCYT1B | c.*234G>A | 3'UTR (SNP) | VAF 90/182 reads (49%) | catalogued as rs746675291; called by muse, varscan2
- ZNF488 | c.-78G>T | 5'UTR (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
